Somatic mutation profile of cancer-model specimen HCM-SANG-0265-C18-85A (3D Organoid; aliquot HCM-SANG-0265-C18-85A-01D-A78M-36), derived from the metastatic tumor of HCMI case HCM-SANG-0265-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0265-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 471c0742-4bb9-47d4-8de2-8ab024db2529.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0265-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0265-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7222a3e4-39cd-425c-adcc-876b1921b782

The open-access MAF lists 219 somatic variants for this specimen: 157 protein-altering or splice-affecting, 42 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 42, Nonsense Mutation 11, Intron 11, Splice Site 7, Frame Shift Del 7, 3'UTR 4, 5'UTR 3, Splice Region 3, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 111/296 reads (38%) | catalogued as rs1060503310, CD941579, CM035803, COSV57394159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 79/157 reads (50%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 302/303 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC6A1 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1396036517, COSV99822786; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 138/139 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 346/348 reads (99%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1619A>G p.Y540C | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV52710061; called by muse, mutect2, varscan2
- ACAN | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs368584197, COSV61358168; called by muse, mutect2, varscan2
- ADAMTS16 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 145/259 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754295364, COSV57009975; called by muse, mutect2, varscan2
- ADAMTS9 | c.630C>G p.S210R | Missense Mutation (SNP) | VAF 96/167 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99898767; called by muse, mutect2, varscan2
- ARHGAP19 | c.1469A>T p.K490I | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as rs759548911; called by muse, mutect2
- ARHGEF37 | c.1467G>A p.P489= | Splice Region (SNP) | VAF 24/86 reads (28%) | catalogued as rs772857613; called by muse, mutect2, varscan2
- CACNA1H | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs60741169; called by muse, mutect2
- CCDC88A | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 64/101 reads (63%) | catalogued as COSV55056392; called by muse, mutect2, varscan2
- CDH6 | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 109/549 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.337); catalogued as COSV99421174; called by muse, mutect2, varscan2
- CDH9 | c.1000-1G>T p.X334_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | catalogued as COSV50276196, COSV50541880, COSV99143658; called by muse, mutect2
- CLCN1 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 192/822 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58368642, COSV58369230; called by muse, mutect2, varscan2
- COL7A1 | c.5923G>A p.E1975K | Missense Mutation (SNP) | VAF 301/302 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.709); catalogued as rs2229821; called by muse, mutect2, varscan2
- CR1L | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs1044838155; called by muse, mutect2, varscan2
- CUBN | c.1201A>C p.S401R | Missense Mutation (SNP) | VAF 87/534 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1434711386; called by muse, mutect2, varscan2
- CYP17A1 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV64004706; called by muse, mutect2, varscan2
- EIF3H | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 441/610 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs200688884; called by muse, mutect2, varscan2
- EOLA2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 341/549 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.311); catalogued as rs781843529; called by muse, mutect2, varscan2
- FAM135B | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV52709678, COSV52718533; called by muse, mutect2, varscan2
- FN1 | c.5186A>C p.K1729T | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.541); catalogued as rs1278941021; called by muse, mutect2, varscan2
- HPSE2 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 96/468 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs745556418, COSV100985808, COSV65196317; called by muse, mutect2, varscan2
- IGHMBP2 | c.2265G>T p.R755S | Missense Mutation (SNP) | VAF 132/712 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446236371; called by muse, varscan2
- JAKMIP1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs745353291, COSV51547338; called by muse, mutect2, varscan2
- KATNAL1 | c.509A>C p.Q170P | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66065082; called by muse, mutect2, varscan2
- MAP9 | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV100250646; called by muse, mutect2, varscan2
- MGAT5B | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs771745922, COSV56936626; called by muse, mutect2, varscan2
- MUC15 | c.431del p.L144Rfs*15 | Frame Shift Del (DEL) | VAF 75/321 reads (23%) | catalogued as COSV55555043; called by mutect2, pindel, varscan2
- NCBP3 | c.692A>T p.D231V | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs765817847; called by muse, mutect2, varscan2
- NXPH2 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs988440643, COSV99740226; called by muse, mutect2, varscan2
- OR13C4 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 71/329 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV52925773; called by muse, mutect2, varscan2
- OR8B4 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.487); catalogued as rs758603752; called by muse, mutect2, varscan2
- P2RY10 | c.457A>G p.S153G | Missense Mutation (SNP) | VAF 125/309 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50681608, COSV50687780; called by muse, mutect2, varscan2
- PCDH7 | c.2165G>C p.R722T | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100687759; called by muse, mutect2
- PCDHGA9 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 17/462 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV53932730; called by muse, mutect2
- PDHA2 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs371163676; called by muse, mutect2, varscan2
- PLA2G4F | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs754233049; called by muse, mutect2, varscan2
- PLCG2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs755569519; called by muse, mutect2, varscan2
- PRSS53 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 135/428 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs371057405; called by muse, mutect2, varscan2
- RHOH | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766809804, COSV67806182; called by muse, mutect2, varscan2
- RPTN | c.1319G>A p.G440D | Missense Mutation (SNP) | VAF 254/885 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV60168890; called by mutect2, varscan2
- RSPO2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 293/405 reads (72%) | catalogued as rs773297160; called by muse, mutect2, varscan2
- SAMD9L | c.2122G>T p.D708Y | Missense Mutation (SNP) | VAF 143/286 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV59081909; called by muse, mutect2, varscan2
- SCN8A | c.2832C>A p.C944* | Nonsense Mutation (SNP) | VAF 49/182 reads (27%) | catalogued as rs1555225839; called by muse, mutect2, varscan2
- SEC24C | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 122/395 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.205); catalogued as rs780721252, COSV100226674; called by muse, mutect2, varscan2
- SPDYE4 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs763254969; called by muse, mutect2, varscan2
- SYT10 | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1356281066, COSV57344622; called by muse, mutect2, varscan2
- TNS1 | c.3862C>T p.H1288Y | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.541); catalogued as COSV50705763; called by muse, mutect2
- TPH1 | c.804A>T p.P268= | Splice Region (SNP) | VAF 17/466 reads (4%) | catalogued as COSV51457850; called by muse, mutect2
- TRIM39 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 121/516 reads (23%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.853); catalogued as rs769468484; called by muse, mutect2, varscan2
- TRO | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs776270129, COSV51497331; called by muse, mutect2
- TTN | c.33768A>C p.K11256N (on ENST00000591111; = p.K10329N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | PolyPhen benign (0.219); catalogued as COSV100623774, COSV60186107, COSV60389020; called by muse, mutect2, varscan2
- UNC80 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 223/224 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466391695; called by muse, mutect2, varscan2
- XKR7 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 133/291 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs748725549, COSV73812885; called by muse, mutect2, varscan2
- ZC3H18 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 184/303 reads (61%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs776103058; called by muse, mutect2, varscan2
- ZEB2 | c.1372A>C p.S458R | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV57960761; called by muse, mutect2, varscan2
- ZNF184 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53003216; called by muse, mutect2, varscan2
- ZNF709 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs762291246; called by muse, mutect2, varscan2
- ZZZ3 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 110/235 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs916523235; called by muse, mutect2, varscan2
- ADAMTS19 | c.2899T>G p.L967V | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- AKAP6 | c.1502C>A p.T501N | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ARHGEF9 | c.1368_1369insC p.G457Rfs*37 | Frame Shift Ins (INS) | VAF 69/340 reads (20%) | called by mutect2, pindel, varscan2
- ARNT2 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRX | c.7298T>C p.L2433P | Missense Mutation (SNP) | VAF 50/496 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ATRX | c.6776A>T p.D2259V | Missense Mutation (SNP) | VAF 37/608 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BSX | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C8B | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CACNB2 | c.303_307delinsACA p.Q102Hfs*28 (on ENST00000324631 / NM_201596.3; = p.Q47Hfs*28 on NM_000724.4) | Frame Shift Del (DEL) | VAF 103/314 reads (33%) | called by pindel, varscan2*
- CDH26 | c.1291C>A p.L431M | Missense Mutation (SNP) | VAF 12/337 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2
- CDRT1 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 84/124 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CEMP1 | c.438G>C p.R146S | Missense Mutation (SNP) | VAF 250/370 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP44 | c.890+2T>C p.X297_splice | Splice Site (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- CFAP47 | c.7510G>C p.D2504H | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CFP | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- CLPSL1 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 126/354 reads (36%) | called by muse, mutect2, varscan2
- CNBD1 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYP7A1 | c.1215+1G>T p.X405_splice | Splice Site (SNP) | VAF 49/461 reads (11%) | called by muse, mutect2, varscan2
- DDX21 | c.2018T>G p.V673G | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- DIAPH2 | c.3256C>A p.P1086T | Missense Mutation (SNP) | VAF 37/377 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- DNAJC27 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- DNAJC3 | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNHD1 | c.13346G>A p.R4449K | Missense Mutation (SNP) | VAF 121/418 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DYNC2H1 | c.8962G>T p.A2988S | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- EZH2 | c.1809C>G p.N603K (on ENST00000460911 / NM_001203247.2; = p.N608K on NM_004456.5) | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- F2RL2 | c.749A>C p.N250T | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- FAM124A | c.1301C>T p.P434L (on ENST00000322475 / NM_001242312.2; = p.P470L on NM_145019.4) | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- FAXDC2 | c.268T>G p.F90V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSHR | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FUT9 | c.623A>C p.E208A | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FXR1 | c.881-1G>C p.X294_splice | Splice Site (SNP) | VAF 59/74 reads (80%) | called by muse, mutect2, varscan2
- GABBR2 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 86/163 reads (53%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GLI3 | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 293/661 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- GPR158 | c.3524A>G p.E1175G | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GPR179 | c.2347G>A p.D783N (on ENST00000621958; = p.D782N on NM_001004334.4) | Missense Mutation (SNP) | VAF 300/301 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRIN2D | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL18R1 | c.49A>G p.S17G | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- ITPR2 | c.5920G>T p.G1974C | Missense Mutation (SNP) | VAF 451/453 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KANSL1L | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KDM1B | c.1079G>T p.G360V (on ENST00000449850; = p.G228V on NM_153042.4) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNDC1 | c.418C>G p.P140A | Missense Mutation (SNP) | VAF 133/408 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LRRC31 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LVRN | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 230/467 reads (49%) | called by muse, mutect2, varscan2
- MAP4K3 | c.1195_1196del p.V399* | Frame Shift Del (DEL) | VAF 67/262 reads (26%) | called by mutect2, pindel, varscan2
- MAST4 | c.643-15_648del p.X215_splice (on ENST00000403625 / NM_001164664.2; = p.X14_splice on NM_015183.3) | Splice Site (DEL) | VAF 37/142 reads (26%) | called by mutect2, pindel, varscan2
- ME2 | c.843A>C p.Q281H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICU3 | c.794G>T p.R265M | Missense Mutation (SNP) | VAF 122/124 reads (98%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NIPAL4 | c.1039G>C p.A347P | Missense Mutation (SNP) | VAF 160/1060 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NPFFR2 | c.1536A>C p.E512D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUDT6 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFM3 | c.1287C>A p.Y429* (on ENST00000338858 / NM_001288821.1; = p.Y409* on NM_058170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- PACRGL | c.731G>A p.C244Y (on ENST00000471979; = p.C217Y on NM_145048.5) | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PARP1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 206/350 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2
- PCLO | c.4600_4601del p.G1534Lfs*5 | Frame Shift Del (DEL) | VAF 26/254 reads (10%) | called by mutect2, pindel
- PCSK1N | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 382/769 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PLCG2 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLCXD3 | c.332_333insG p.Y111* | Nonsense Mutation (INS) | VAF 51/219 reads (23%) | called by mutect2, pindel, varscan2
- PLPP4 | c.321-1G>A p.X107_splice | Splice Site (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- PSKH2 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSME3 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PTPRT | c.2144C>A p.T715N | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- SLAMF8 | c.608T>A p.V203D | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SLC26A8 | c.1709T>G p.L570R | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC3A1 | c.192del p.Y65Mfs*41 | Frame Shift Del (DEL) | VAF 114/416 reads (27%) | called by mutect2, pindel, varscan2
- SPART | c.1874T>G p.L625R | Missense Mutation (SNP) | VAF 148/531 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31D1 | c.878del p.A293Vfs*19 | Frame Shift Del (DEL) | VAF 58/456 reads (13%) | called by mutect2, varscan2
- SPINK5 | c.2693A>C p.K898T | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); called by muse, mutect2
- SYNDIG1 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, varscan2
- SYNE1 | c.23763A>T p.E7921D (on ENST00000367255 / NM_182961.4; = p.E7850D on NM_033071.3) | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.957T>G p.I319M (on ENST00000367255 / NM_182961.4; = p.I326M on NM_033071.3) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TADA1 | c.692+1G>A p.X231_splice | Splice Site (SNP) | VAF 58/81 reads (72%) | called by muse, mutect2, varscan2
- TAF9B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 82/486 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TDRD15 | c.1067T>C p.L356P | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.4304A>G p.D1435G | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TENM4 | c.2197T>A p.C733S | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2
- THBD | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- THBS4 | c.221T>A p.I74N | Missense Mutation (SNP) | VAF 40/685 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2
- TMEM244 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TRAV8-4 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM69 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.025); called by muse, mutect2
- TRPV5 | c.1122+6T>G | Splice Region (SNP) | VAF 196/374 reads (52%) | called by muse, mutect2, varscan2
- TTC27 | c.1725A>T p.E575D | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TTN | c.22610A>G p.Q7537R (on ENST00000591111; = p.Q6610R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/107 reads (47%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TUB | c.1300G>A p.D434N (on ENST00000299506 / NM_177972.3; = p.D489N on NM_003320.4) | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TUBGCP2 | c.2627G>T p.R876M | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- TUBGCP2 | c.2626A>G p.R876G | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- VAT1L | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- WAS | c.1336A>T p.K446* | Nonsense Mutation (SNP) | VAF 17/297 reads (6%) | called by muse, mutect2
- WNK4 | c.1769G>T p.S590I | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XCR1 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 171/377 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZFP36L2 | c.1466del p.L489Pfs*13 | Frame Shift Del (DEL) | VAF 114/445 reads (26%) | called by mutect2, pindel, varscan2
- ZNF630 | c.1285A>G p.K429E | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ZNF638 | c.2393C>A p.A798D | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF75D | c.1408A>C p.T470P | Missense Mutation (SNP) | VAF 59/516 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ABCB1 | c.1611G>A p.Q537= | Silent (SNP) | VAF 139/531 reads (26%) | catalogued as rs201960151; called by muse, mutect2, varscan2
- BMP6 | c.540C>T p.H180= | Silent (SNP) | VAF 47/293 reads (16%) | catalogued as rs776483805; called by muse, mutect2, varscan2
- C2orf16 | c.4326A>G p.R1442= | Silent (SNP) | VAF 39/305 reads (13%) | called by muse, mutect2, varscan2
- C4A | c.3573C>T p.H1191= | Silent (SNP) | VAF 274/1122 reads (24%) | catalogued as rs776084081, COSV101418309; called by muse, mutect2, varscan2
- C4BPB | c.546G>A p.G182= | Silent (SNP) | VAF 51/335 reads (15%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.3093C>T p.I1031= | Silent (SNP) | VAF 148/296 reads (50%) | called by muse, mutect2, varscan2
- COL11A2 | c.2076C>T p.H692= (on ENST00000341947 / NM_080680.3; = p.H585= on NM_080679.2) | Silent (SNP) | VAF 85/120 reads (71%) | catalogued as rs144713192; called by muse, mutect2, varscan2
- COL12A1 | c.5358T>G p.T1786= | Silent (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- COL4A1 | c.243T>A p.T81= | Silent (SNP) | VAF 70/441 reads (16%) | called by muse, mutect2, varscan2
- DENND3 | c.2925C>T p.S975= | Silent (SNP) | VAF 125/643 reads (19%) | called by muse, mutect2, varscan2
- FAM189A2 | c.411C>G p.P137= | Silent (SNP) | VAF 108/221 reads (49%) | called by muse, mutect2, varscan2
- FAM47C | c.489C>G p.G163= | Silent (SNP) | VAF 63/343 reads (18%) | catalogued as rs782247299; called by muse, mutect2, varscan2
- FLT4 | c.2673C>T p.R891= | Silent (SNP) | VAF 20/261 reads (8%) | catalogued as COSV56107993, COSV56110115; called by muse, mutect2
- GNE | c.1746C>T p.I582= (on ENST00000396594 / NM_001128227.3; = p.I551= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/530 reads (7%) | called by muse, mutect2
- GPM6A | c.384T>C p.A128= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2
- KIF26B | c.2436G>A p.S812= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs1256029069; called by muse, mutect2, varscan2
- KLHL29 | c.165G>A p.P55= | Silent (SNP) | VAF 148/459 reads (32%) | catalogued as rs781234171, COSV72085706; called by muse, mutect2, varscan2
- KPRP | c.1260G>A p.P420= | Silent (SNP) | VAF 168/499 reads (34%) | called by muse, mutect2, varscan2
- MEIS2 | c.603A>G p.E201= (on ENST00000561208 / NM_170675.5; = p.E188= on NM_002399.3) | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- METTL21C | c.552T>C p.A184= | Silent (SNP) | VAF 109/313 reads (35%) | called by muse, mutect2, varscan2
- NBEA | c.6612C>T p.H2204= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as rs369263902; called by muse, mutect2, varscan2
- NHS | c.93C>T p.S31= | Silent (SNP) | VAF 385/550 reads (70%) | called by muse, mutect2, varscan2
- NR5A1 | c.777G>A p.P259= | Silent (SNP) | VAF 164/335 reads (49%) | catalogued as rs529716231; called by muse, mutect2, varscan2
- OR6K2 | c.510G>A p.S170= | Silent (SNP) | VAF 104/145 reads (72%) | catalogued as rs746548556, COSV100656738, COSV62743283; called by muse, mutect2, varscan2
- PAPPA | c.2931A>G p.Q977= | Silent (SNP) | VAF 163/348 reads (47%) | catalogued as rs749773269; called by muse, mutect2, varscan2
- PCDH19 | c.858C>T p.R286= | Silent (SNP) | VAF 179/522 reads (34%) | catalogued as rs779759129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGA12 | c.1773G>C p.V591= | Silent (SNP) | VAF 325/631 reads (52%) | called by muse, mutect2, varscan2
- PDE8B | c.1512T>C p.L504= | Silent (SNP) | VAF 105/520 reads (20%) | called by muse, mutect2, varscan2
- PLPP7 | c.399G>C p.L133= | Silent (SNP) | VAF 64/144 reads (44%) | called by muse, mutect2, varscan2
- PTPRT | c.2145C>A p.T715= | Silent (SNP) | VAF 16/267 reads (6%) | called by muse, mutect2
- RBMXL2 | c.960C>T p.S320= | Silent (SNP) | VAF 130/195 reads (67%) | catalogued as COSV60978749; called by muse, mutect2, varscan2
- RNF121 | c.315A>T p.L105= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- SEC14L5 | c.1788G>T p.G596= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as COSV52036564; called by muse, mutect2, varscan2
- SIGLEC7 | c.231A>G p.P77= | Silent (SNP) | VAF 69/334 reads (21%) | catalogued as rs1478213617; called by muse, mutect2, varscan2
- SLAMF8 | c.609C>A p.V203= | Silent (SNP) | VAF 58/330 reads (18%) | called by muse, mutect2, varscan2
- TENM1 | c.2013T>C p.T671= | Silent (SNP) | VAF 81/767 reads (11%) | catalogued as COSV64425148, COSV64437386; called by muse, mutect2, varscan2
- TRIM4 | c.280C>T p.L94= | Silent (SNP) | VAF 15/235 reads (6%) | catalogued as rs1246819819; called by muse, mutect2
- VCX2 | c.189G>A p.T63= | Silent (SNP) | VAF 261/700 reads (37%) | catalogued as rs770368909; called by muse, mutect2, varscan2
- VWF | c.6867C>G p.V2289= | Silent (SNP) | VAF 16/579 reads (3%) | catalogued as COSV54620045; called by muse, mutect2
- WASF3 | c.690C>T p.S230= | Silent (SNP) | VAF 70/196 reads (36%) | catalogued as rs755635136, COSV58964199; called by muse, mutect2, varscan2
- ZNF221 | c.150C>T p.A50= | Silent (SNP) | VAF 46/262 reads (18%) | called by muse, mutect2, varscan2
- ZNF804A | c.435A>G p.R145= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.-46G>A | 5'UTR (SNP) | VAF 233/233 reads (100%) | called by muse, mutect2, varscan2
- ALDH6A1 | c.49-3204T>C | Intron (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- ALOX12 | c.1161+653G>A | Intron (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- AP2A2 | c.*660G>A | 3'UTR (SNP) | VAF 88/326 reads (27%) | catalogued as rs781676435; called by muse, mutect2, varscan2
- CPLANE1 | c.*740C>T | 3'UTR (SNP) | VAF 25/125 reads (20%) | catalogued as rs139940282; called by muse, mutect2, varscan2
- DIRC3 | n.492A>C | RNA (SNP) | VAF 17/95 reads (18%) | catalogued as COSV70404166; called by muse, mutect2, varscan2
- DISC1 | c.1634+3668C>T | Intron (SNP) | VAF 104/164 reads (63%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+660G>C | Intron (SNP) | VAF 137/382 reads (36%) | called by muse, mutect2, varscan2
- HECTD3 | c.*4G>A | 3'UTR (SNP) | VAF 47/102 reads (46%) | catalogued as rs767740586; called by muse, mutect2
- NOVA1 | c.136+722A>G | Intron (SNP) | VAF 79/178 reads (44%) | called by muse, mutect2, varscan2
- PACRGL | c.-16-2610C>G | Intron (SNP) | VAF 79/172 reads (46%) | called by muse, mutect2, varscan2
- PAX6 | c.142-54T>A | Intron (SNP) | VAF 129/412 reads (31%) | called by muse, mutect2, varscan2
- SERPINA1 | c.-4-16dup | Intron (INS) | VAF 51/132 reads (39%) | catalogued as rs768968701; called by mutect2, varscan2
- SH3BGRL3 | c.-61C>T | 5'UTR (SNP) | VAF 125/251 reads (50%) | catalogued as rs1271261382; called by muse, mutect2, varscan2
- SYNPR | c.540+1194A>G | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- TAZ | c.*520C>T | 3'UTR (SNP) | VAF 262/816 reads (32%) | catalogued as rs1046945823; called by muse, mutect2, varscan2
- TSPAN12 | c.-47_-44dup | 5'UTR (INS) | VAF 97/538 reads (18%) | called by mutect2, pindel, varscan2
- TTN | c.6509-30T>A | Intron (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.6509-31C>T | Intron (SNP) | VAF 18/145 reads (12%) | catalogued as rs1025693779; called by muse, mutect2, varscan2
- ZNF849P | n.74G>T | RNA (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
